Somatic mutation profile of tumor specimen TCGA-KL-8327-01A (aliquot TCGA-KL-8327-01A-11D-2310-10) from TCGA case TCGA-KL-8327, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 46.9 years (17,121 days).
Specimen TCGA-KL-8327-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84dcbc68-3c43-46c9-b0f1-3c650e00fef1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8327-11A (Solid Tissue Normal), aliquot TCGA-KL-8327-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0037b1a5-d169-4359-93a5-3cf2f7df5189

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV56066167, COSV56074712; called by muse, mutect2, varscan2
- CACNA1C | c.5347G>A p.G1783S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs781633980, COSV59707133; called by muse, mutect2, varscan2
- CSF1R | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs1256984931, COSV53834937; called by muse, mutect2, varscan2
- FAM189B | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs534103219, COSV56946385; called by muse, mutect2, varscan2
- ITIH6 | c.2071G>A p.G691R | Missense Mutation (SNP) | VAF 24/554 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99513638; called by muse, mutect2
- TCF4 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs869312695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF14 | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100694099, COSV59848851; called by muse, mutect2
- ACTL10 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- AXDND1 | c.1574_1575insC p.E525Dfs*22 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel*
- CDH2 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- DBP | c.917_939del p.Q306Rfs*29 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by mutect2, pindel
- HSPA12B | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PPRC1 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC8 | c.1587C>T p.C529= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs1451685338; called by muse, varscan2
- RCVRN | c.258C>T p.Y86= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs764982768, COSV56841335, COSV99874156; called by muse, mutect2, varscan2
- GCNT1 | c.*3661_*3662del | 3'UTR (DEL) | VAF 12/118 reads (10%) | called by mutect2, varscan2
- ZBTB33 | c.*565C>A | 3'UTR (SNP) | VAF 9/123 reads (7%) | catalogued as COSV100434240; called by muse, mutect2
